Gene-level copy-number profile of tumor specimen TCGA-VN-A88R-01A from TCGA case TCGA-VN-A88R, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.4 years (19,513 days).
Specimen TCGA-VN-A88R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a7805dfe-86cf-4190-9b2b-74b5e5ea0f8b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VN-A88R-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b9727f9d-539c-4b3d-83d1-1c5e4cf52b72

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1; copy number 2: 6,227; copy number 3: 937; copy number 4: 51,389; copy number 5: 2; copy number 6: 877; copy number 7: 34; copy number 8: 14; copy number 9: 311; copy number 10: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VN-A88R-01A-11D-A363-01): tumor purity 0.79, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:77,343,557–78,946,440, 7 genes: AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1.
- chr6:104,687,241–105,454,062, 15 genes: AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3.
- chr8:135,455,865–135,456,952, 1 gene: AC040914.1.
- chr8:137,105,352–137,645,564, 3 genes (within-gene range 0–2): RNU6-144P, ZYXP1, AC105213.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 313 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,811,768–146,251,179, 244 genes, copy number 9 (broad region; genes not listed).
- chr3:147,590,996–147,846,657, 2 genes, copy number 10: NPM1P28, AC092925.1.
- chr3:148,791,102–151,080,726, 67 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
